Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017976-09A.2 (aliquot TARGET-15-SJMPAL017976-09A.2-01D) from TARGET case TARGET-15-SJMPAL017976, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.7 years (5,022 days).
Specimen TARGET-15-SJMPAL017976-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 519a6227-dfc6-4c95-a652-7202b30f93f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017976-10A (Blood Derived Normal), aliquot TARGET-15-SJMPAL017976-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d99bf14-309d-420e-86ff-a531d626b57e

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Frame Shift Ins 4, Silent 4, Nonsense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 52/181 reads (29%) | catalogued as rs397515401, CM122406, COSV60107754, COSV60115393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 66/127 reads (52%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- CSMD3 | c.4558T>G p.F1520V (on ENST00000297405 / NM_001363185.1; = p.F1416V on NM_052900.3) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52268332; called by muse, mutect2
- DBH | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs781667738; called by muse, mutect2, varscan2
- IPO7 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV65684130; called by muse, mutect2, varscan2
- KALRN | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.997); catalogued as rs367667422; called by muse, mutect2, varscan2
- OR7C2 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.317); catalogued as rs1197723389; called by muse, mutect2, varscan2
- PDE1A | c.1051G>T p.G351W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59522275; called by muse, mutect2, varscan2
- PLXNA4 | c.4910G>A p.R1637Q | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs753325197, COSV58127821; called by muse, mutect2, varscan2
- SMURF1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs371859465, COSV63157556, COSV63159073; called by muse, varscan2
- TAF4 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376636061; called by muse, mutect2, varscan2
- TGFA | c.368G>T p.C123F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs1465708840; called by muse, mutect2
- WT1 | c.1101_1102insGGGGC p.R368Gfs*71 | Frame Shift Ins (INS) | VAF 54/126 reads (43%) | catalogued as COSV100189346, COSV60065589, COSV60066153, COSV60066283, COSV60067539, COSV60069909, COSV60077657, COSV60077667, COSV60077683, COSV60078403, COSV60079676, COSV60084998, COSV60085351; called by pindel, varscan2
- WT1 | c.1069delinsGG p.R357Gfs*16 | Frame Shift Ins (INS) | VAF 31/114 reads (27%) | catalogued as CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; called by pindel, varscan2*
- ANKHD1-EIF4EBP3 | c.3980_3981insTGAGATACTG p.P1328Efs*15 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- CREBBP | c.4769_4770insGGGC p.N1590Kfs*28 | Frame Shift Ins (INS) | VAF 17/212 reads (8%) | called by mutect2, pindel
- ENKD1 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2
- PTGES | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD2 | c.7573A>T p.K2525* | Nonsense Mutation (SNP) | VAF 46/51 reads (90%) | called by muse, mutect2, varscan2
- TRPC4 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- FLT3 | c.2502A>G p.R834= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV54057915; called by muse, varscan2
- GOLGA8O | c.507C>T p.R169= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as rs778644601; called by muse, mutect2, varscan2
- LCAT | c.66C>T p.A22= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs910206058; called by muse, mutect2, varscan2
- NKX2-2 | c.54G>T p.L18= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- VKORC1 | c.173+130A>G | Intron (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
